Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QI, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QI-01C (Primary Tumor).

[page 1 of 2]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Surgical Pathology Report

ICD O-3
Carcinoma, renal cell chromophobe type
Site R Kidney NOS C64.9
831713
9/24/13

PATIENT:
ACCOUNT#:
DOB:
AGE: SEX: F
ATTENDING:
REQUESTING:
CONTACT NO:
COPIES TO:

MRN:
RECEIVED DATE:
PROCEDURE DATE:
SIGN-OUT DATE:
LOCATION:
ROOM:

DIAGNOSIS: Kidney, right, mass, excision: Renal cell carcinoma, chromophobe type, Fuhrman nuclear Grade 2; see note.

CLINICAL INFORMATION: Brief Clinical History: BHD/R renal mass Specimen Taken For Protocol:
Requestor Name Requestor Phone/Pager:
Admitting Protocol Number:

PROCEDURE: Pre-Operative Diagnosis: R Renal Mass Post-Operative Diagnosis: R
Renal Mass Operative Findings: See dictated operative report

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT, Renal mass

GROSS DESCRIPTION: Received fresh for procurement labeled with the patient's name and medical record number and "right renal mass" is a 4 x 3.5 x 3 cm circular red mass. Per surgeon, no margins are necessary. The specimen is bisected revealing a tan/fed cut surface with punctate hemorrhagic-like areas. Half the specimen is procured for Research for the and the remaining half is sent to Pathology. At Surgical Pathology, the specimen received matches the above. The specimen is serially sectioned to reveal a homogeneous, soft, fleshy to spongy cut surface that is pale yellow to tan in color. Representative full-thickness sections are submitted in

Gross dictated by

No consultants

Patient Identification

[page 2 of 2]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Date of Report:

Criteria	W 9/13/13	Yes	No
Primary Tumor Site Discrepancy	No TX		✓
Prior Malignancy History	UNK + Melanoma	✓	

Patient Identification

Source: NCI Genomic Data Commons file ed7fae92-b865-4fa7-b298-673db8fc283e (TCGA-KM-A7QI.ED4BE998-2781-4316-8FB0-DE2E657C6E7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).